Somatic mutation profile of tumor specimen TCGA-E1-A7YU-01A (aliquot TCGA-E1-A7YU-01A-11D-A34J-08) from TCGA case TCGA-E1-A7YU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 42.0 years (15,345 days).
Specimen TCGA-E1-A7YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1c08de7-b561-474e-8393-fe517a65751f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YU-10A (Blood Derived Normal), aliquot TCGA-E1-A7YU-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/228bf4ee-1ba4-40d8-a6c6-cbc674926460

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 25/40 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHRNB3 | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496877; called by muse, mutect2, varscan2
- CPO | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368297452, COSV55941035; called by muse, mutect2, varscan2
- DZIP3 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV64313260; called by muse, mutect2, varscan2
- EDEM3 | c.748-1G>A p.X250_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100545028; called by muse, mutect2, varscan2
- KDM1B | c.1009G>A p.V337I (on ENST00000449850; = p.V205I on NM_153042.4) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs201513146, COSV52813507; called by muse, mutect2, varscan2
- KNL1 | c.1486T>C p.S496P (on ENST00000346991 / NM_170589.5; = p.S470P on NM_144508.5) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV61158754; called by muse, mutect2, varscan2
- LDHC | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV99772373; called by muse, mutect2, varscan2
- POLA2 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs751395996, COSV55485308; called by muse, mutect2, varscan2
- SCAF11 | c.4297G>A p.V1433I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs917016159, COSV65478326; called by muse, mutect2, varscan2
- SF3B1 | c.1772T>A p.V591E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV59222682; called by muse, mutect2, varscan2
- TBC1D2 | c.291T>G p.S97R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1240767704, COSV59787616; called by muse, mutect2, varscan2
- TLL2 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs747500669, COSV100780564, COSV63574175; called by muse, mutect2, varscan2
- VPS13D | c.11072C>G p.T3691S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.343); catalogued as COSV99165805; called by muse, mutect2, varscan2
- WDR49 | c.43T>C p.S15P (on ENST00000308378 / NM_001366158.1; = p.S356P on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV57702912; called by muse, mutect2, varscan2
- IGKV1-12 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PSMB3 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CALCOCO2 | c.42G>A p.L14= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99363693; called by muse, mutect2, varscan2
- CC2D1A | c.498C>T p.Y166= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs373022042; called by muse, mutect2, varscan2
- DSEL | c.3480T>G p.S1160= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100025398; called by muse, mutect2, varscan2
- MPG | c.387G>T p.G129= | Silent (SNP) | VAF 69/194 reads (36%) | catalogued as COSV99549847; called by muse, mutect2, varscan2
- PCDHA6 | c.84C>T p.S28= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as COSV100972180; called by muse, mutect2, varscan2
- SYNCRIP | c.1521T>C p.A507= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs745778681, COSV100784104; called by muse, mutect2, varscan2
- ZNF99 | c.*541G>A | 3'UTR (SNP) | VAF 25/71 reads (35%) | catalogued as COSV101233756; called by muse, mutect2, varscan2
